Somatic mutation profile of tumor specimen TCGA-CN-4733-01A (aliquot TCGA-CN-4733-01A-02D-1870-08) from TCGA case TCGA-CN-4733, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.8 years (22,561 days).
Specimen TCGA-CN-4733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42c2a66e-8309-41db-a200-a649915d9ca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4733-10A (Blood Derived Normal), aliquot TCGA-CN-4733-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd092b3b-2dfb-4328-ae41-373dbddab874

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554190823, COSV61005010; called by muse, mutect2
- ADCY4 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100156927, COSV60253529; called by muse, mutect2
- CARD10 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); catalogued as rs746538476, COSV52654713; called by muse, mutect2, varscan2
- DNAH5 | c.13790A>G p.Y4597C | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99445534; called by muse, mutect2
- ERC1 | c.1376A>T p.K459M | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV100706921; called by muse, mutect2
- RBM10 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61311090; called by muse, mutect2
- SLC17A8 | c.355-2A>G p.X119_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100035939; called by muse, mutect2
- TMPO | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs934283851, COSV100587870; called by muse, mutect2
- ZNF821 | c.247A>T p.K83* (on ENST00000425432 / NM_001376297.1; = p.K41* on NM_017530.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100546940; called by muse, mutect2
- ANK2 | c.11514G>A p.E3838= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100004700; called by muse, mutect2, varscan2
- ARID1A | c.2667C>T p.G889= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100253836; called by muse, mutect2
- COASY | c.963C>G p.L321= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99888888; called by muse, mutect2
- MARF1 | c.2067G>A p.P689= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs775796864, COSV100706489; called by muse, mutect2
